Gene-level copy-number profile of tumor specimen C3L-06395-05 from CPTAC case C3L-06395, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 62.7 years (22,896 days).
Specimen C3L-06395-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5290db93-b3dd-483a-812e-f128222a78bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06395-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/993d3f67-cfd5-4038-949e-cf17d6f32de6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 23; copy number 2: 20,439; copy number 3: 8,060; copy number 4: 26,959; copy number 5: 3,163; copy number 6: 131; copy number 7: 1; copy number 8: 11; copy number 36: 2; copy number 40: 4; copy number 43: 13; copy number 44: 77; copy number 239: 23.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:19,230,435–19,373,545, 3 genes (within-gene range 0–2): DENND4C, AL161909.2, AL391834.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 119 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,201,595–1,295,068, 4 genes, copy number 40: SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:12,794,100–12,795,522, 2 genes, copy number 36 (within-gene range 2–36): AC106794.2, AC106794.1.
- chr5:15,384,220–16,440,081, 13 genes, copy number 43: MARK2P5, AC114964.2, AC114964.1, FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1.
- chr12:22,409,237–24,562,544, 15 genes, copy number 44 (within-gene range 3–44): AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1.
- chr12:31,254,361–32,993,754, 62 genes, copy number 44 (broad region; genes not listed).
- chr17:11,598,470–13,306,771, 23 genes, copy number 239: DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
